Somatic mutation profile of tumor specimen C3L-00913-03 (aliquot CPT0106110009) from CPTAC case C3L-00913, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 66.7 years (24,378 days).
Specimen C3L-00913-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7e099ff5-7355-4711-9c5e-7557dc83b77b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00913-31 (Blood Derived Normal), aliquot CPT0107080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a5836a9-5076-4575-b12e-2696eb5d0c78

The open-access MAF lists 316 somatic variants for this specimen: 215 protein-altering or splice-affecting, 69 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 183, Silent 69, Intron 16, Nonsense Mutation 14, Frame Shift Del 7, Splice Site 5, RNA 5, 3'UTR 4, Splice Region 3, Frame Shift Ins 3, 3'Flank 3, 5'UTR 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.37G>T p.G13C | Missense Mutation (SNP) | VAF 57/463 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs121913535, COSV55497378, COSV55502117, COSV55509530; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 32/186 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- AGMO | c.128C>A p.A43E | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1286930315, COSV61110171, COSV61125734; called by muse, mutect2
- ANO3 | c.241+1G>T p.X81_splice | Splice Site (SNP) | VAF 17/148 reads (11%) | catalogued as rs376533875, COSV99884414; called by muse, varscan2
- APOB | c.5002G>C p.E1668Q | Missense Mutation (SNP) | VAF 23/348 reads (7%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.999); catalogued as rs766898429; called by muse, mutect2
- ARMCX5 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs778633013; called by muse, mutect2, varscan2
- ASTN2 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV57781195; called by muse, mutect2, varscan2
- ATP1A3 | c.2047G>C p.E683Q (on ENST00000545399 / NM_001256214.2; = p.E670Q on NM_152296.5) | Missense Mutation (SNP) | VAF 163/573 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.081); catalogued as COSV57486709; called by muse, mutect2, varscan2
- BCHE | c.1749G>T p.M583I | Missense Mutation (SNP) | VAF 54/363 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.084); catalogued as rs1337284571; called by muse, mutect2, varscan2
- BMPR2 | c.1575G>A p.M525I | Missense Mutation (SNP) | VAF 35/527 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs774669361; called by muse, mutect2
- BTBD9 | c.955C>T p.R319C | Missense Mutation (SNP) | VAF 52/439 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs1361502014; called by muse, mutect2, varscan2
- CD8B | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 32/316 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.282); catalogued as rs967089228, COSV100514798; called by muse, varscan2
- CELF3 | c.615C>A p.S205R | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.325); catalogued as rs750652603; called by muse, mutect2
- CENPBD1 | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 13/261 reads (5%) | catalogued as rs879850437; called by muse, mutect2
- CEP192 | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as rs1370313863; called by muse, mutect2, varscan2
- CFAP52 | c.1435G>A p.A479T | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs766179265, COSV55347006; called by muse, mutect2, varscan2
- CFHR5 | c.868G>C p.G290R | Missense Mutation (SNP) | VAF 46/406 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs893593079; called by muse, varscan2
- CREB5 | c.430A>T p.I144F (on ENST00000357727 / NM_182898.4; = p.I137F on NM_004904.3) | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63219921; called by muse, mutect2, varscan2
- CRLF3 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 20/468 reads (4%) | catalogued as rs1300240812, COSV60835616; called by muse, mutect2
- CSMD3 | c.1540G>T p.E514* (on ENST00000297405 / NM_001363185.1; = p.E410* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 87/543 reads (16%) | catalogued as COSV52111067; called by muse, mutect2, varscan2
- CYTIP | c.931G>T p.G311* | Nonsense Mutation (SNP) | VAF 32/438 reads (7%) | catalogued as COSV51635200; called by muse, mutect2
- DDR1 | c.979G>T p.G327W | Missense Mutation (SNP) | VAF 9/111 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.319); catalogued as rs1295077270, COSV100242201; called by muse, mutect2
- DDX23 | c.641G>A p.R214H | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs768510377, COSV57282225; called by muse, mutect2
- EEF2K | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.353); catalogued as rs931055938; called by muse, mutect2
- EIF3M | c.531G>A p.K177= | Splice Region (SNP) | VAF 12/220 reads (5%) | catalogued as rs1010049438; called by muse, mutect2
- FGF3 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 55/366 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as rs929527246, COSV61925190; called by muse, mutect2, varscan2
- GDF7 | c.1284C>G p.I428M | Missense Mutation (SNP) | VAF 19/338 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99693964; called by muse, mutect2
- GOLGA6D | c.1806G>T p.K602N | Missense Mutation (SNP) | VAF 23/591 reads (4%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1428912194; called by muse, mutect2
- GRIP2 | c.754G>T p.G252C (on ENST00000619221; = p.G155C on NM_001080423.4) | Missense Mutation (SNP) | VAF 28/241 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99817637; called by muse, mutect2, varscan2
- HCFC1 | c.4636G>T p.A1546S | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as COSV100129630; called by muse, mutect2, varscan2
- ITPR1 | c.4052C>G p.S1351C (on ENST00000354582; = p.S1336C on NM_002222.7) | Missense Mutation (SNP) | VAF 14/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56979752; called by muse, mutect2
- KIAA1549L | c.5377C>A p.L1793M (on ENST00000321505; = p.L2090M on NM_012194.3) | Missense Mutation (SNP) | VAF 45/355 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100382260; called by muse, mutect2, varscan2
- KMT2D | c.4160G>C p.G1387A | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM156342, COSV56464267, COSV56482157, COSV56500236; called by muse, mutect2
- KRTAP19-3 | c.97C>A p.R33S | Missense Mutation (SNP) | VAF 36/499 reads (7%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV100477445; called by muse, mutect2
- LRPPRC | c.2168G>T p.R723L | Missense Mutation (SNP) | VAF 67/551 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs754760201; called by muse, mutect2, varscan2
- LRRIQ4 | c.1585G>A p.E529K | Missense Mutation (SNP) | VAF 24/477 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.444); catalogued as rs755826280; called by muse, mutect2
- MAGEE1 | c.579T>A p.D193E | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as COSV63911235; called by muse, mutect2, varscan2
- MCM6 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV99918858; called by muse, mutect2, varscan2
- MS4A3 | c.558C>G p.C186W | Missense Mutation (SNP) | VAF 17/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs778541342, COSV53934779; called by muse, mutect2
- MYL3 | c.454G>C p.E152Q | Missense Mutation (SNP) | VAF 22/241 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as CM0910617; called by muse, mutect2
- NLRC5 | c.4751+1G>A p.X1584_splice | Splice Site (SNP) | VAF 26/231 reads (11%) | catalogued as rs1456514968; called by muse, mutect2, varscan2
- OR13C4 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 20/182 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs75737900; called by muse, mutect2, varscan2
- OR1L3 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.055); catalogued as rs200264223, COSV59170367; called by muse, mutect2, varscan2
- OR8B4 | c.768C>G p.F256L | Missense Mutation (SNP) | VAF 21/348 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.013); catalogued as COSV100635789, COSV62069259; called by muse, mutect2
- PCDH15 | c.4917C>G p.D1639E (on ENST00000644397 / NM_001354429.2; = p.D1581E on NM_001142771.2) | Missense Mutation (SNP) | VAF 51/489 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.996); catalogued as COSV64698780; called by muse, mutect2, varscan2
- PKHD1 | c.2020C>T p.L674F | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV61885754; called by muse, mutect2, varscan2
- PRMT8 | c.1128G>T p.L376F | Missense Mutation (SNP) | VAF 50/435 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV54212894; called by muse, mutect2, varscan2
- RTL3 | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs376343340, COSV100329889; called by muse, mutect2, varscan2
- RXFP3 | c.1193A>C p.K398T | Missense Mutation (SNP) | VAF 16/314 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV57505982; called by muse, mutect2
- SI | c.3992G>T p.W1331L | Missense Mutation (SNP) | VAF 40/440 reads (9%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.924); catalogued as rs776755426, COSV52281830; called by muse, mutect2
- SIRPB1 | c.722G>T p.G241V | Missense Mutation (SNP) | VAF 48/452 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99498326; called by muse, mutect2
- SKAP2 | c.136G>A p.E46K | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.067); catalogued as COSV100591753; called by muse, mutect2
- SLC5A4 | c.735G>T p.E245D | Missense Mutation (SNP) | VAF 35/296 reads (12%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as COSV56669549; called by muse, varscan2
- SNX8 | c.1105G>A p.V369M | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as rs1332097758; called by muse, mutect2
- SYCE1 | c.869C>G p.P290R (on ENST00000343131 / NM_001143764.3; = p.P254R on NM_130784.3) | Missense Mutation (SNP) | VAF 31/348 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.776); catalogued as COSV58219684; called by muse, mutect2
- TASOR2 | c.4882G>A p.G1628S | Missense Mutation (SNP) | VAF 32/430 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV60168571; called by muse, mutect2
- TBC1D22A | c.1310G>C p.R437P | Missense Mutation (SNP) | VAF 41/252 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61438177; called by muse, mutect2, varscan2
- TFRC | c.1549G>A p.V517I | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs768134450; called by muse, mutect2
- TLR7 | c.1003T>A p.F335I | Missense Mutation (SNP) | VAF 43/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101027967; called by muse, mutect2, varscan2
- TMPRSS11A | c.57G>T p.M19I | Missense Mutation (SNP) | VAF 9/244 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV58358548; called by muse, mutect2
- TRADD | c.842C>T p.T281M | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61460674; called by muse, mutect2
- USP16 | c.769C>T p.L257F | Missense Mutation (SNP) | VAF 26/189 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1249213418; called by muse, mutect2, varscan2
- ZNF865 | c.1613C>T p.A538V | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.12); catalogued as rs756303683; called by muse, mutect2, varscan2
- ABCB11 | c.1477T>C p.W493R | Missense Mutation (SNP) | VAF 15/388 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- AC019068.1 | n.397G>C | Splice Region (SNP) | VAF 13/107 reads (12%) | called by muse, mutect2, varscan2
- ACTN2 | c.2551C>A p.R851S | Missense Mutation (SNP) | VAF 29/454 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.372); called by muse, mutect2
- ADAD2 | c.547C>G p.L183V (on ENST00000315906 / NM_001145400.2; = p.L255V on NM_139174.4) | Missense Mutation (SNP) | VAF 36/311 reads (12%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ADAMTS14 | c.2543C>A p.T848N | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.288); called by muse, mutect2
- ADAMTS17 | c.511G>T p.G171C | Missense Mutation (SNP) | VAF 23/621 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); called by muse, mutect2
- ADAMTS20 | c.1041C>G p.H347Q | Missense Mutation (SNP) | VAF 40/314 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.981); called by muse, varscan2
- ADCY9 | c.3947T>G p.V1316G | Missense Mutation (SNP) | VAF 23/456 reads (5%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); called by muse, mutect2
- ADD2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 46/351 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADGRB3 | c.2506A>T p.T836S | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADGRG7 | c.1106C>A p.P369Q | Missense Mutation (SNP) | VAF 30/284 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.086); called by muse, varscan2
- AGBL1 | c.2432G>T p.S811I | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- AGBL3 | c.754C>T p.H252Y | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.07); called by muse, mutect2
- AOC1 | c.311G>A p.G104D | Missense Mutation (SNP) | VAF 39/351 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGAP9 | c.1037G>T p.G346V | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); called by muse, mutect2
- ATM | c.8672-2A>G p.X2891_splice | Splice Site (SNP) | VAF 75/493 reads (15%) | called by muse, mutect2, varscan2
- BCAS2 | c.224C>G p.A75G | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.345); called by muse, mutect2
- BCKDHB | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- C19orf84 | c.326G>A p.W109* | Nonsense Mutation (SNP) | VAF 8/119 reads (7%) | called by muse, mutect2
- CCDC168 | c.8592G>C p.K2864N | Missense Mutation (SNP) | VAF 19/289 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); called by muse, mutect2
- CCDC175 | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 38/190 reads (20%) | called by muse, mutect2, varscan2
- CD6 | c.1909C>A p.Q637K | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2
- CEMIP | c.3574G>A p.D1192N | Missense Mutation (SNP) | VAF 58/461 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- CEP104 | c.1624_1628del p.A542Pfs*16 | Frame Shift Del (DEL) | VAF 26/316 reads (8%) | called by mutect2, pindel
- CEP170B | c.1975G>T p.G659C (on ENST00000453495; = p.G588C on NM_015005.3) | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CHRM1 | c.557C>A p.P186H | Missense Mutation (SNP) | VAF 35/292 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- CHST5 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- CLIP2 | c.947G>T p.S316I | Missense Mutation (SNP) | VAF 69/600 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- COG4 | c.1542G>T p.Q514H | Missense Mutation (SNP) | VAF 56/563 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- COL20A1 | c.3814C>A p.P1272T | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.538); called by muse, mutect2, varscan2
- COMP | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COQ9 | c.394A>C p.S132R | Missense Mutation (SNP) | VAF 38/646 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.265); called by muse, mutect2
- COX5B | c.8C>T p.S3L | Missense Mutation (SNP) | VAF 27/286 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2
- CSMD3 | c.8955dup p.P2986Tfs*9 (on ENST00000297405 / NM_001363185.1; = p.P2817Tfs*9 on NM_052900.3) | Frame Shift Ins (INS) | VAF 47/384 reads (12%) | called by mutect2, pindel, varscan2
- CTCFL | c.802A>G p.R268G | Missense Mutation (SNP) | VAF 24/235 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CYP19A1 | c.442T>G p.F148V | Missense Mutation (SNP) | VAF 52/440 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAH11 | c.5337G>T p.Q1779H | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2
- DNM1L | c.2076_2106del p.K692Nfs*16 (on ENST00000549701 / NM_012062.5; = p.K655Nfs*16 on NM_005690.4) | Frame Shift Del (DEL) | VAF 84/642 reads (13%) | called by mutect2, pindel
- EGFL6 | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPHA7 | c.1895G>C p.C632S | Missense Mutation (SNP) | VAF 11/259 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- EPHX4 | c.908G>A p.W303* | Nonsense Mutation (SNP) | VAF 27/239 reads (11%) | called by muse, mutect2, varscan2
- ESRP1 | c.494T>G p.L165* | Nonsense Mutation (SNP) | VAF 36/177 reads (20%) | called by muse, mutect2, varscan2
- ETAA1 | c.1283C>G p.S428* | Nonsense Mutation (SNP) | VAF 10/129 reads (8%) | called by muse, mutect2
- FAM47A | c.1439C>A p.P480Q | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.974); called by muse, varscan2
- FAM47B | c.566del p.P189Rfs*161 | Frame Shift Del (DEL) | VAF 24/130 reads (18%) | called by mutect2, pindel, varscan2
- FFAR4 | c.553C>G p.P185A | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FIGN | c.339G>T p.L113F | Missense Mutation (SNP) | VAF 44/444 reads (10%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.931); called by muse, mutect2
- FREM2 | c.3242A>G p.D1081G | Missense Mutation (SNP) | VAF 41/662 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- FSIP2 | c.18426G>T p.Q6142H | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- GDF10 | c.1360C>T p.L454F | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRIN3A | c.2011T>A p.W671R | Missense Mutation (SNP) | VAF 50/441 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- GRM5 | c.1198G>T p.V400L | Missense Mutation (SNP) | VAF 67/413 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HIVEP2 | c.6237del p.R2080Efs*6 | Frame Shift Del (DEL) | VAF 24/251 reads (10%) | called by mutect2, pindel
- HMCN2 | c.13676G>T p.R4559L | Missense Mutation (SNP) | VAF 44/465 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2
- HRH3 | c.289_299del p.T97Dfs*48 | Frame Shift Del (DEL) | VAF 34/300 reads (11%) | called by mutect2, pindel
- HTR2C | c.825G>T p.E275D | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT tolerated (0.67); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IGKV1D-17 | c.99G>C p.M33I | Missense Mutation (SNP) | VAF 81/958 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- IGKV2D-24 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 33/307 reads (11%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- IGKV2D-30 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- IMPG2 | c.602del p.P201Hfs*30 | Frame Shift Del (DEL) | VAF 34/430 reads (8%) | called by mutect2, pindel
- IQCB1 | c.959dup p.V321Cfs*21 | Frame Shift Ins (INS) | VAF 42/416 reads (10%) | called by mutect2, pindel
- JMJD1C | c.640G>C p.D214H | Missense Mutation (SNP) | VAF 23/261 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- KCNC2 | c.731C>A p.T244K | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.373); called by muse, mutect2
- KIAA2026 | c.3757A>G p.N1253D | Missense Mutation (SNP) | VAF 50/412 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KLHL31 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- KRTAP10-10 | c.534C>A p.C178* | Nonsense Mutation (SNP) | VAF 41/656 reads (6%) | called by muse, mutect2
- KRTAP20-3 | c.38A>G p.Y13C | Missense Mutation (SNP) | VAF 28/203 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- LAMA3 | c.4046C>G p.P1349R | Missense Mutation (SNP) | VAF 42/562 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRFN5 | c.238C>A p.L80M | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC7 | c.110T>A p.L37Q (on ENST00000651989 / NM_001370785.2; = p.L4Q on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRIQ1 | c.4490G>T p.C1497F | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- MAMLD1 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MAP1LC3C | c.55T>A p.L19M | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- MCM6 | c.1370G>A p.C457Y | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ME1 | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- MGRN1 | c.48C>G p.D16E | Missense Mutation (SNP) | VAF 20/339 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.257); called by muse, mutect2
- MROH2A | c.2835G>T p.K945N | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MSLN | c.116G>T p.G39V | Missense Mutation (SNP) | VAF 8/167 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.006); called by muse, mutect2
- MUC16 | c.36803C>A p.P12268H | Missense Mutation (SNP) | VAF 32/233 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- MUC17 | c.9107T>A p.I3036K | Missense Mutation (SNP) | VAF 20/206 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.134); called by muse, mutect2
- MUC2 | c.842G>T p.W281L | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MYRF | c.3268C>A p.P1090T (on ENST00000278836 / NM_001127392.3; = p.P1050T on NM_013279.4) | Missense Mutation (SNP) | VAF 26/274 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NBPF12 | c.2399-2A>T p.X800_splice | Splice Site (SNP) | VAF 14/633 reads (2%) | called by muse, mutect2
- NBPF4 | c.1879C>T p.P627S | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- NFKB2 | c.1261G>T p.A421S | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2, varscan2
- OGA | c.1737dup p.R580Tfs*10 | Frame Shift Ins (INS) | VAF 28/264 reads (11%) | called by mutect2, pindel
- OR1E1 | c.457A>G p.T153A | Missense Mutation (SNP) | VAF 60/443 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- OR2AJ1 | c.504C>A p.F168L | Missense Mutation (SNP) | VAF 28/212 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- OR2F2 | c.780C>G p.I260M | Missense Mutation (SNP) | VAF 44/314 reads (14%) | SIFT tolerated (1); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- OR51S1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 23/247 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ORC3 | c.927del p.L310* | Frame Shift Del (DEL) | VAF 23/220 reads (10%) | called by mutect2, varscan2
- PCF11 | c.3061G>A p.E1021K | Missense Mutation (SNP) | VAF 54/369 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PCF11 | c.3106G>T p.A1036S | Missense Mutation (SNP) | VAF 47/341 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCLO | c.13754G>T p.C4585F | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDSS2 | c.297-1G>T p.X99_splice | Splice Site (SNP) | VAF 29/596 reads (5%) | called by muse, mutect2
- PLA2G4D | c.1359A>T p.E453D | Missense Mutation (SNP) | VAF 22/175 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PLCB4 | c.124G>A p.D42N | Missense Mutation (SNP) | VAF 17/244 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- PLXNA3 | c.2639G>T p.R880L | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- POU5F2 | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 45/497 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2
- PPP1R3F | c.1355A>G p.Q452R | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- PPP1R3F | c.1356G>T p.Q452H | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.275); called by muse, mutect2
- PPP5C | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 67/256 reads (26%) | called by muse, mutect2, varscan2
- PTPRC | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 77/612 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- PTPRT | c.4066G>A p.V1356M | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.195); called by muse, mutect2
- PYROXD2 | c.1252C>T p.Q418* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- RAB11FIP3 | c.1181G>T p.G394V | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- RALGAPA1 | c.5665G>A p.D1889N | Missense Mutation (SNP) | VAF 27/445 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); called by muse, mutect2
- REV3L | c.6737T>G p.L2246R | Missense Mutation (SNP) | VAF 19/276 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); called by muse, mutect2
- RHOB | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 18/205 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); called by muse, mutect2
- RIMS1 | c.3806G>A p.R1269K | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2
- RPGRIP1L | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2
- RYR2 | c.3900G>C p.M1300I | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR2 | c.7672G>A p.G2558S | Missense Mutation (SNP) | VAF 23/408 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.989); called by muse, mutect2
- SBSN | c.255A>T p.K85N | Missense Mutation (SNP) | VAF 116/389 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SCAPER | c.2172G>T p.R724S | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SCAPER | c.2171G>A p.R724K | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2
- SEC23IP | c.74C>T p.S25F | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.603); called by muse, mutect2
- SEZ6L | c.2215G>T p.V739L | Missense Mutation (SNP) | VAF 35/239 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SH3PXD2B | c.756G>C p.Q252H | Missense Mutation (SNP) | VAF 36/470 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.573); called by muse, mutect2
- SH3RF3 | c.1345G>T p.A449S | Missense Mutation (SNP) | VAF 18/287 reads (6%) | SIFT tolerated (0.99); PolyPhen benign (0.005); called by muse, mutect2
- SLC25A18 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 22/185 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SLC27A5 | c.1808C>T p.P603L | Missense Mutation (SNP) | VAF 16/166 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.25); called by muse, mutect2
- SLC30A10 | c.90C>A p.Y30* | Nonsense Mutation (SNP) | VAF 26/344 reads (8%) | called by muse, mutect2
- SLC43A2 | c.1203G>C p.E401D | Missense Mutation (SNP) | VAF 36/344 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC5A1 | c.477G>T p.S159= | Splice Region (SNP) | VAF 36/489 reads (7%) | called by muse, mutect2
- SLC6A17 | c.1986G>T p.K662N | Missense Mutation (SNP) | VAF 41/317 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SLC8A1 | c.2719C>G p.L907V | Missense Mutation (SNP) | VAF 27/289 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SLITRK2 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 19/167 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SMOX | c.130C>A p.L44I | Missense Mutation (SNP) | VAF 16/450 reads (4%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.994); called by muse, mutect2
- SMURF1 | c.1672G>A p.E558K | Missense Mutation (SNP) | VAF 16/261 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- SNTG1 | c.967G>T p.V323L | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- SOX6 | c.1131G>T p.M377I (on ENST00000528429 / NM_001145819.2; = p.M336I on NM_017508.3) | Missense Mutation (SNP) | VAF 48/405 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SPATA31D1 | c.761A>G p.E254G | Missense Mutation (SNP) | VAF 20/712 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2
- SYNE1 | c.1660G>T p.E554* (on ENST00000367255 / NM_182961.4; = p.E561* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 29/264 reads (11%) | called by muse, mutect2, varscan2
- TCTE1 | c.558T>A p.N186K | Missense Mutation (SNP) | VAF 32/218 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TENM3 | c.2761C>A p.P921T | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- TMEM171 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 17/390 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.031); called by muse, mutect2
- TMTC1 | c.793C>A p.L265M (on ENST00000539277 / NM_001193451.2; = p.L157M on NM_175861.3) | Missense Mutation (SNP) | VAF 17/212 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.172); called by muse, mutect2
- TREML4 | c.442A>T p.T148S | Missense Mutation (SNP) | VAF 35/351 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.431); called by muse, mutect2
- UGT2B15 | c.358T>A p.Y120N | Missense Mutation (SNP) | VAF 15/339 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.062); called by muse, mutect2
- USH2A | c.2402G>T p.G801V | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTP20 | c.7636G>A p.D2546N | Missense Mutation (SNP) | VAF 27/270 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VIPAS39 | c.177G>T p.W59C | Missense Mutation (SNP) | VAF 91/636 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VSIG1 | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.034); called by muse, varscan2
- VWA5B1 | c.2666G>A p.S889N | Missense Mutation (SNP) | VAF 34/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDR59 | c.2351G>T p.S784I | Missense Mutation (SNP) | VAF 16/192 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.724); called by muse, mutect2
- ZFPM2 | c.1294G>A p.A432T | Missense Mutation (SNP) | VAF 34/574 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2
- ZNF358 | c.1222G>T p.A408S | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF439 | c.395A>G p.N132S | Missense Mutation (SNP) | VAF 47/383 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF717 | c.2330A>T p.Q777L | Missense Mutation (SNP) | VAF 38/415 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2
- ZNF724 | c.94G>C p.V32L | Missense Mutation (SNP) | VAF 35/268 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- ZP4 | c.1118C>A p.T373N | Missense Mutation (SNP) | VAF 22/154 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ADGRB2 | c.903G>C p.G301= | Silent (SNP) | VAF 36/310 reads (12%) | called by muse, mutect2, varscan2
- ADGRG4 | c.2538C>T p.S846= | Silent (SNP) | VAF 33/135 reads (24%) | called by muse, mutect2, varscan2
- ADGRG4 | c.3393C>A p.T1131= | Silent (SNP) | VAF 37/127 reads (29%) | catalogued as COSV54960073; called by muse, mutect2, varscan2
- AEBP1 | c.384C>A p.T128= | Silent (SNP) | VAF 48/610 reads (8%) | called by muse, mutect2
- ALPK2 | c.2361C>A p.T787= | Silent (SNP) | VAF 25/232 reads (11%) | called by muse, mutect2, varscan2
- ATP1A4 | c.2358G>C p.L786= | Silent (SNP) | VAF 30/246 reads (12%) | catalogued as rs760807198, COSV100927552; called by muse, mutect2, varscan2
- AZIN2 | c.717C>T p.F239= | Silent (SNP) | VAF 19/200 reads (10%) | called by muse, mutect2
- C10orf71 | c.3936C>A p.I1312= | Silent (SNP) | VAF 22/210 reads (10%) | called by muse, mutect2
- CD40LG | c.57C>T p.I19= | Silent (SNP) | VAF 62/264 reads (23%) | called by muse, mutect2, varscan2
- CHD5 | c.258G>A p.S86= | Silent (SNP) | VAF 46/362 reads (13%) | catalogued as rs777535759; called by muse, varscan2
- COX7B2 | c.57G>T p.L19= | Silent (SNP) | VAF 44/251 reads (18%) | catalogued as COSV57213816; called by muse, mutect2, varscan2
- DDX25 | c.150C>T p.I50= | Silent (SNP) | VAF 13/238 reads (5%) | catalogued as COSV99700035; called by muse, mutect2
- DOCK5 | c.2814G>A p.R938= | Silent (SNP) | VAF 12/247 reads (5%) | called by muse, mutect2
- DSP | c.4143C>A p.T1381= | Silent (SNP) | VAF 38/225 reads (17%) | called by muse, mutect2, varscan2
- EGFR | c.2331G>T p.L777= | Silent (SNP) | VAF 40/319 reads (13%) | called by muse, mutect2, varscan2
- ESRP1 | c.495A>G p.L165= | Silent (SNP) | VAF 36/176 reads (20%) | catalogued as COSV64409832; called by muse, mutect2, varscan2
- FAM118A | c.888A>G p.P296= | Silent (SNP) | VAF 10/176 reads (6%) | called by muse, mutect2
- FAM193A | c.3267C>T p.L1089= | Silent (SNP) | VAF 37/480 reads (8%) | catalogued as rs1264190434; called by muse, mutect2
- FSIP2 | c.6897T>C p.F2299= | Silent (SNP) | VAF 21/165 reads (13%) | called by muse, mutect2, varscan2
- GABRA3 | c.381G>A p.L127= | Silent (SNP) | VAF 29/361 reads (8%) | called by muse, mutect2
- GDF10 | c.627C>A p.I209= | Silent (SNP) | VAF 16/166 reads (10%) | catalogued as rs373114581; called by muse, mutect2
- GLT6D1 | c.495G>A p.E165= | Silent (SNP) | VAF 26/257 reads (10%) | called by muse, mutect2
- ITGAM | c.1227C>A p.A409= | Silent (SNP) | VAF 16/145 reads (11%) | called by muse, mutect2
- KCND3 | c.18G>C p.A6= | Silent (SNP) | VAF 25/242 reads (10%) | called by muse, mutect2, varscan2
- KCNE2 | c.183T>A p.S61= | Silent (SNP) | VAF 20/382 reads (5%) | called by muse, mutect2
- KNSTRN | c.105A>G p.L35= | Silent (SNP) | VAF 63/433 reads (15%) | catalogued as rs768924814; called by muse, mutect2, varscan2
- KRTAP10-10 | c.87C>A p.P29= | Silent (SNP) | VAF 43/219 reads (20%) | called by muse, mutect2, varscan2
- L1CAM | c.2982G>A p.Q994= | Silent (SNP) | VAF 101/252 reads (40%) | called by muse, mutect2, varscan2
- LRRTM3 | c.795C>A p.I265= | Silent (SNP) | VAF 42/361 reads (12%) | catalogued as rs1383934730, COSV63662267, COSV63667855; called by muse, mutect2, varscan2
- MAGEB18 | c.255C>A p.A85= | Silent (SNP) | VAF 54/218 reads (25%) | called by muse, mutect2, varscan2
- MAN1B1 | c.750G>A p.Q250= | Silent (SNP) | VAF 24/572 reads (4%) | called by muse, mutect2
- MAPRE2 | c.66G>A p.G22= | Silent (SNP) | VAF 15/164 reads (9%) | called by muse, mutect2
- MFN2 | c.351C>G p.L117= | Silent (SNP) | VAF 36/592 reads (6%) | called by muse, mutect2
- MSGN1 | c.471G>A p.Q157= | Silent (SNP) | VAF 20/392 reads (5%) | catalogued as COSV55264018; called by muse, mutect2
- MUC16 | c.36804C>A p.P12268= | Silent (SNP) | VAF 32/236 reads (14%) | called by muse, mutect2, varscan2
- NOBOX | c.924G>T p.T308= | Silent (SNP) | VAF 31/391 reads (8%) | catalogued as COSV56199511; called by muse, mutect2
- OPA1 | c.720A>G p.Q240= (on ENST00000361510 / NM_130837.3; = p.Q204= on NM_130832.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/342 reads (5%) | called by muse, mutect2
- OR10AG1 | c.300C>G p.G100= | Silent (SNP) | VAF 23/218 reads (11%) | called by muse, mutect2, varscan2
- OR1K1 | c.123G>A p.L41= | Silent (SNP) | VAF 32/348 reads (9%) | catalogued as COSV52957310; called by muse, mutect2
- OR2G2 | c.774C>T p.I258= | Silent (SNP) | VAF 17/326 reads (5%) | catalogued as rs865888004; called by muse, mutect2
- OR2T27 | c.249C>G p.V83= | Silent (SNP) | VAF 22/454 reads (5%) | called by muse, mutect2
- OR3A2 | c.903C>G p.L301= | Silent (SNP) | VAF 7/105 reads (7%) | called by muse, mutect2
- OR4C13 | c.255T>C p.Y85= | Silent (SNP) | VAF 46/710 reads (6%) | called by muse, mutect2
- OR51B6 | c.222C>A p.T74= | Silent (SNP) | VAF 23/160 reads (14%) | called by muse, mutect2, varscan2
- OR5D13 | c.600A>G p.L200= | Silent (SNP) | VAF 45/438 reads (10%) | called by muse, mutect2, varscan2
- ORC4 | c.6C>T p.S2= | Silent (SNP) | VAF 14/378 reads (4%) | called by muse, mutect2
- PATJ | c.90G>T p.S30= | Silent (SNP) | VAF 38/286 reads (13%) | catalogued as rs201592994; called by muse, mutect2, varscan2
- PLCL1 | c.2022G>T p.P674= | Silent (SNP) | VAF 25/236 reads (11%) | catalogued as rs558973603, COSV70822050; called by muse, mutect2, varscan2
- PPP1R3A | c.3027G>A p.G1009= | Silent (SNP) | VAF 60/604 reads (10%) | called by muse, mutect2, varscan2
- RICTOR | c.3660C>T p.F1220= | Silent (SNP) | VAF 15/272 reads (6%) | called by muse, mutect2
- RNF213 | c.7068C>T p.L2356= | Silent (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- SCAF8 | c.1881C>G p.V627= | Silent (SNP) | VAF 8/228 reads (4%) | called by muse, mutect2
- SFXN5 | c.816C>T p.S272= | Silent (SNP) | VAF 19/160 reads (12%) | catalogued as COSV99730103; called by muse, mutect2, varscan2
- SIGLEC6 | c.654G>T p.T218= | Silent (SNP) | VAF 19/308 reads (6%) | catalogued as COSV58435779; called by muse, mutect2
- SLC4A5 | c.1278G>C p.V426= | Silent (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2
- SLCO4A1 | c.1026G>T p.A342= | Silent (SNP) | VAF 32/225 reads (14%) | catalogued as rs747026694; called by muse, mutect2, varscan2
- ST18 | c.1074A>G p.S358= | Silent (SNP) | VAF 9/82 reads (11%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.291G>A p.Q97= | Silent (SNP) | VAF 7/164 reads (4%) | called by muse, mutect2
- STIL | c.687G>C p.G229= | Silent (SNP) | VAF 24/288 reads (8%) | called by muse, mutect2
- STXBP5L | c.1134C>A p.V378= | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as COSV56509497; called by muse, mutect2
- SYT4 | c.459G>A p.K153= | Silent (SNP) | VAF 18/324 reads (6%) | catalogued as COSV54902430; called by muse, mutect2
- TAFA5 | c.432C>T p.P144= | Silent (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- TENM1 | c.573A>G p.R191= | Silent (SNP) | VAF 10/118 reads (8%) | called by muse, mutect2
- THOP1 | c.108C>T p.R36= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100310594; called by muse, mutect2, varscan2
- TRPC4 | c.2472G>T p.V824= (on ENST00000379705 / NM_016179.4; = p.V829= on NM_003306.3) | Silent (SNP) | VAF 13/242 reads (5%) | called by muse, mutect2
- TTC37 | c.1005C>T p.I335= | Silent (SNP) | VAF 57/545 reads (10%) | catalogued as rs774106534, COSV62454858; called by muse, mutect2, varscan2
- VANGL1 | c.546G>T p.V182= | Silent (SNP) | VAF 73/721 reads (10%) | called by muse, mutect2, varscan2
- VSIG4 | c.570A>C p.V190= | Silent (SNP) | VAF 55/242 reads (23%) | called by muse, mutect2, varscan2
- WDR72 | c.930C>T p.C310= | Silent (SNP) | VAF 46/391 reads (12%) | catalogued as rs1166504434; called by muse, mutect2, varscan2
- AC244258.1 | n.311-4964T>A | Intron (SNP) | VAF 22/260 reads (8%) | called by muse, mutect2
- AC244517.10 | c.36-8836C>A | Intron (SNP) | VAF 107/561 reads (19%) | catalogued as COSV73145192; called by muse, mutect2, varscan2
- ACSF3 | c.*315G>T | 3'UTR (SNP) | VAF 11/302 reads (4%) | called by muse, mutect2
- ADAM10 | c.207-10329A>G | Intron (SNP) | VAF 12/298 reads (4%) | called by muse, mutect2
- ANO4 | c.-87C>A | 5'UTR (SNP) | VAF 16/172 reads (9%) | catalogued as COSV54593142; called by muse, mutect2
- ASH1L | c.5828+4629A>T | Intron (SNP) | VAF 66/520 reads (13%) | called by muse, mutect2, varscan2
- ASPSCR1 | c.*14G>A | 3'UTR (SNP) | VAF 20/206 reads (10%) | called by muse, mutect2
- BCHE | c.*9T>C | 3'UTR (SNP) | VAF 29/231 reads (13%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+39000G>A | Intron (SNP) | VAF 19/448 reads (4%) | called by muse, mutect2
- BTNL9 | c.955+566G>T | Intron (SNP) | VAF 39/243 reads (16%) | called by muse, mutect2, varscan2
- CAPRIN2 | c.2148+1602G>T | Intron (SNP) | VAF 21/181 reads (12%) | called by muse, mutect2, varscan2
- CEP295 | chr11:93735126 A>G | 3'Flank (SNP) | VAF 16/87 reads (18%) | catalogued as rs987417464; called by muse, mutect2, varscan2
- CFAP20 | c.465+22G>C | Intron (SNP) | VAF 39/375 reads (10%) | catalogued as rs1483500733; called by muse, mutect2, varscan2
- CIB4 | c.186+5878C>A | Intron (SNP) | VAF 26/390 reads (7%) | called by muse, mutect2
- CSN1S2AP | n.345C>T | RNA (SNP) | VAF 16/306 reads (5%) | called by muse, mutect2
- EIF2B5 | c.1327-19G>C | Intron (SNP) | VAF 28/574 reads (5%) | called by muse, mutect2
- FAM183BP | n.365del | RNA (DEL) | VAF 4/43 reads (9%) | called by mutect2, pindel, varscan2
- GP2 | chr16:20327710 G>A | 5'Flank (SNP) | VAF 37/350 reads (11%) | called by muse, mutect2, varscan2
- ITGB3BP | c.485-715C>G | Intron (SNP) | VAF 22/262 reads (8%) | called by muse, mutect2
- MIR323A | n.33T>A | RNA (SNP) | VAF 35/277 reads (13%) | called by muse, mutect2, varscan2
- MRAP | chr21:32314651 T>C | 3'Flank (SNP) | VAF 33/330 reads (10%) | called by muse, mutect2
- NDRG4 | c.37+687G>A | Intron (SNP) | VAF 29/251 reads (12%) | catalogued as rs978136703; called by muse, mutect2, varscan2
- NOC2LP2 | n.525G>T | RNA (SNP) | VAF 85/685 reads (12%) | called by muse, mutect2, varscan2
- PDE2A | c.703+66G>T | Intron (SNP) | VAF 22/212 reads (10%) | called by muse, varscan2
- PTPRO | c.-22_-21del | 5'UTR (DEL) | VAF 37/321 reads (12%) | called by mutect2, pindel, varscan2
- RANBP1 | c.-13C>T | 5'UTR (SNP) | VAF 15/114 reads (13%) | called by muse, mutect2, varscan2
- RXFP2 | c.*33C>T | 3'UTR (SNP) | VAF 16/251 reads (6%) | called by muse, mutect2
- SATB2 | c.-60+1807C>T | Intron (SNP) | VAF 12/216 reads (6%) | called by muse, mutect2
- SPATA31D5P | n.334G>T | RNA (SNP) | VAF 35/266 reads (13%) | catalogued as rs1368735736; called by muse, mutect2, varscan2
- TCP11 | c.124+708C>G | Intron (SNP) | VAF 20/374 reads (5%) | catalogued as COSV55132902; called by muse, mutect2
- Y_RNA | chr7:23490785 C>G | 3'Flank (SNP) | VAF 24/354 reads (7%) | called by muse, mutect2
- ZC3H15 | c.1090+612A>T | Intron (SNP) | VAF 13/322 reads (4%) | called by muse, mutect2
